MMRF case MMRF_1266 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5bcce914-6efa-4c0e-a0d7-7806e28b919c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.2 years (27,094 days); ISS stage: I; Days to last known disease status: 1,457 days (4.0 years); Days to last follow up: 1,457 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,314 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 408 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,314 days (3.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 3.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.051 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 39.8 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 1.45 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 9.4 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 0.12 mg/dL.
- Day 78 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.801 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.663 mg/dL; Immunoglobulin G 4.15 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 4.35 mmol/L.
- Day 162 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.683 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.664 mg/dL; Immunoglobulin G 3.72 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.97 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 5.6 g/dL; Glucose 3.41 mmol/L.
- Day 288 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.814 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.804 mg/dL; Immunoglobulin G 4.39 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 4.37 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 6.77 mmol/L.
- Day 407 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.783 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.503 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 7.26 mmol/L.
- Day 512 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.761 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.818 mg/dL; Immunoglobulin G 5.51 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 688: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.649 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.611 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.57 mmol/L.
- Day 786 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.878 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.774 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 974 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.858 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.848 mg/dL; Immunoglobulin G 6.07 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 1,079: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 5.92 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.42 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.29 mmol/L.
- Day 1,114 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.971 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.848 mg/dL; Immunoglobulin G 5.43 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.73 mmol/L.
- Day 1,312: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 7.32 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.65 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.89 mmol/L.
- Day 1,457 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 7.28 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -13: Weight: 61 kg; Height: 156 cm.

Biospecimens (2 samples)
- Sample MMRF_1266_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1266_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
